Somatic mutation profile of tumor specimen TCGA-BJ-A45E-01A (aliquot TCGA-BJ-A45E-01A-11D-A23U-08) from TCGA case TCGA-BJ-A45E, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 46.9 years (17,115 days).
Specimen TCGA-BJ-A45E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c39c9e0-1613-4471-9c55-d49229a05841.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A45E-10A (Blood Derived Normal), aliquot TCGA-BJ-A45E-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6862b382-6134-49f7-875e-20352e05f751

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RBP3 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782095820; ClinVar: uncertain significance; called by muse, mutect2
- ITGB7 | c.2088G>A p.Q696= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as COSV57239229; called by muse, mutect2, varscan2
- ZNF335 | c.3720A>G p.E1240= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs763575505, COSV100532751; ClinVar: likely benign; called by muse, mutect2
